Somatic mutation profile of tumor specimen C3L-02951-02 (aliquot CPT0197150009) from CPTAC case C3L-02951, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,502 days).
Specimen C3L-02951-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fec4d15e-ae44-4aa2-9fa8-5e08d0386391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02951-31 (Blood Derived Normal), aliquot CPT0197840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49623bef-a20e-4d02-9de7-1bdd6e5d63f7

The open-access MAF lists 481 somatic variants for this specimen: 323 protein-altering or splice-affecting, 91 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 91, Intron 28, Nonsense Mutation 24, RNA 13, 5'UTR 10, Splice Site 9, 3'UTR 9, Frame Shift Del 7, 5'Flank 6, In Frame Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 34/284 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1111457, COSV64291669, COSV64295080, COSV64295612; called by muse, mutect2, varscan2
- ABCB4 | c.3398T>C p.I1133T (on ENST00000265723 / NM_018849.3; = p.I1126T on NM_000443.4) | Missense Mutation (SNP) | VAF 44/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55939802; called by muse, mutect2, varscan2
- ADAM33 | c.1813A>T p.T605S | Missense Mutation (SNP) | VAF 83/602 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.338); catalogued as rs778859218; called by muse, mutect2, varscan2
- AIFM2 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV100325614, COSV57160313; called by muse, mutect2, varscan2
- ANGPTL6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1271324087; called by muse, mutect2
- ANKS1B | c.2805C>A p.H935Q (on ENST00000547776 / NM_152788.4; = p.H161Q on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100227710; called by muse, mutect2
- ARHGAP31 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 45/409 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99957427; called by muse, mutect2, varscan2
- BHLHA15 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 56/503 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52006303; called by muse, varscan2
- C1orf87 | c.1272+1G>A p.X424_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | catalogued as COSV64599252; called by muse, mutect2
- CACNA1C | c.2132T>G p.V711G | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59732926; called by muse, mutect2, varscan2
- CBLL2 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100081399; called by muse, mutect2, varscan2
- CD80 | c.700+2T>C p.X234_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as rs1384073127; called by muse, mutect2, varscan2
- CETP | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs774703022; called by muse, mutect2
- CHUK | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100957284; called by muse, mutect2, varscan2
- COL15A1 | c.1984C>A p.P662T | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV100897302; called by muse, mutect2, varscan2
- COL5A1 | c.3140C>T p.P1047L | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV65672606; called by muse, mutect2, varscan2
- CREBBP | c.6011G>C p.R2004P | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99270488; called by muse, mutect2
- CTNND2 | c.2235C>A p.Y745* | Nonsense Mutation (SNP) | VAF 45/388 reads (12%) | catalogued as COSV100475089, COSV58885948; called by muse, mutect2, varscan2
- DHX9 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as rs1409649447; called by muse, mutect2, varscan2
- DROSHA | c.1031G>T p.W344L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs1026615218; called by mutect2, varscan2
- ELFN1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs755536565, COSV101300319; called by muse, mutect2, varscan2
- EMX2 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV71294761; called by muse, mutect2, varscan2
- ENDOU | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 34/270 reads (13%) | catalogued as rs969373290; called by muse, mutect2, varscan2
- EPX | c.1466G>T p.R489L | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs370170164; called by muse, mutect2, varscan2
- ESPNL | c.2845G>A p.G949R | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs757439212, COSV58033164; called by muse, mutect2, varscan2
- FAM25A | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 51/442 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as rs370390585; called by muse, mutect2, varscan2
- FAM47A | c.290T>G p.L97R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV60496593; called by muse, mutect2, varscan2
- FLG | c.3986C>A p.S1329* | Nonsense Mutation (SNP) | VAF 26/530 reads (5%) | catalogued as rs755097194, COSV64241642; called by muse, mutect2
- GMEB1 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV53793325; called by muse, mutect2, varscan2
- GMPS | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1351411216; called by muse, mutect2
- GOLGB1 | c.8218A>G p.M2740V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200564559; called by muse, mutect2, varscan2
- GOLGB1 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs376106917; called by muse, mutect2, varscan2
- HERC5 | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as rs1358056166; called by muse, mutect2
- HID1 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs200779853, COSV59351660; called by muse, mutect2, varscan2
- HSPA8 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 25/504 reads (5%) | catalogued as COSV57084271; called by muse, mutect2
- KCNH5 | c.2266T>G p.S756A | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.164); catalogued as COSV59757381; called by muse, mutect2
- KCNV1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 62/644 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV52088969; called by muse, mutect2
- KIF5C | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 12/291 reads (4%) | catalogued as rs1227924385, COSV68479799, COSV68482449; called by muse, mutect2
- LCT | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs1361864298; called by muse, mutect2, varscan2
- LIFR | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1164659009; called by muse, mutect2
- LRGUK | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as COSV53645528; called by muse, mutect2, varscan2
- LRMDA | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV65266973; called by muse, mutect2
- LRRCC1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV100835367; called by muse, mutect2
- MBD6 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100851789; called by muse, mutect2
- MFN1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV54941122; called by muse, mutect2
- MUL1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | catalogued as rs941378215, COSV51641903; called by muse, mutect2, varscan2
- MYH7 | c.3803G>C p.R1268P | Missense Mutation (SNP) | VAF 61/797 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397516194; ClinVar: uncertain significance; called by muse, mutect2
- NCAM2 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV53076669; called by muse, mutect2, varscan2
- NHSL2 | c.1717G>A p.G573R (on ENST00000510661; = p.G939R on NM_001013627.2) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1330890932; called by muse, mutect2, varscan2
- NLRP7 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 27/253 reads (11%) | catalogued as COSV60176850; called by muse, mutect2, varscan2
- NPAP1 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV100274883; called by muse, mutect2
- NUP58 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV101098928; called by muse, mutect2, varscan2
- OBSCN | c.11550G>T p.Q3850H | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV52746679; called by muse, mutect2
- OR14I1 | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100700462; called by muse, mutect2, varscan2
- OR2G2 | c.301T>A p.L101M | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV60740528; called by muse, mutect2, varscan2
- OR51D1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766734057; called by muse, mutect2
- OR5D13 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62333002; called by muse, mutect2, varscan2
- OR5M8 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as COSV59116035; called by muse, mutect2
- PCDH15 | c.3125C>A p.P1042H | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.839); catalogued as COSV100220572; called by muse, mutect2
- PCDHA5 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 84/599 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV65349075; called by muse, mutect2, varscan2
- PDE6B | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs758535671; called by muse, mutect2, varscan2
- PIKFYVE | c.5870G>C p.R1957T | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777180780; called by muse, mutect2
- PIP5K1C | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99080421; called by muse, mutect2, varscan2
- PKHD1L1 | c.3818T>A p.M1273K | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV65749658; called by muse, mutect2, varscan2
- POLR1F | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV55998989; called by muse, mutect2
- PRAMEF6 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 74/1375 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as rs1300062889; called by muse, mutect2
- PXDN | c.3292C>T p.L1098F | Missense Mutation (SNP) | VAF 167/768 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs757055936; called by muse, mutect2, varscan2
- RENBP | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs781907475; called by muse, mutect2, varscan2
- RFTN2 | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as rs754623132, COSV54386302; called by muse, mutect2, varscan2
- RGS7 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100464791; called by muse, mutect2, varscan2
- RHOXF2 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 96/470 reads (20%) | catalogued as COSV65047963, COSV65048062; called by muse, mutect2, varscan2
- SH2B1 | c.1546G>T p.G516C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100450831; called by muse, mutect2, varscan2
- SHOC2 | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs730881021; called by muse, mutect2, varscan2
- SI | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV52296345; called by muse, mutect2
- SLC24A4 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 24/278 reads (9%) | catalogued as COSV54107316; called by muse, mutect2
- SLC9A4 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54829172; called by muse, mutect2
- SPTA1 | c.5552T>C p.L1851S | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs745975472; called by muse, mutect2
- STYXL2 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54807873; called by muse, mutect2
- TACC2 | c.8624A>T p.Q2875L (on ENST00000334433; = p.Q953L on NM_006997.4) | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385348085; called by muse, mutect2, varscan2
- TBC1D23 | c.709A>T p.I237F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV61370115; called by muse, mutect2, varscan2
- TF | c.649G>C p.G217R | Missense Mutation (SNP) | VAF 12/388 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs921313476; called by muse, mutect2
- TMCC2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 63/469 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.679); catalogued as rs1241187031; called by muse, mutect2, varscan2
- TP53 | c.1045del p.E349Nfs*21 | Frame Shift Del (DEL) | VAF 49/315 reads (16%) | catalogued as COSV52696505; called by mutect2, pindel, varscan2
- TRAJ36 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 26/183 reads (14%) | catalogued as rs1166610661; called by muse, mutect2, varscan2
- TRPA1 | c.1545G>T p.W515C | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51575416; called by muse, varscan2
- TSNAXIP1 | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.563); catalogued as COSV54649425; called by muse, mutect2, varscan2
- TTN | c.97271C>T p.S32424L (on ENST00000591111; = p.S25000L on NM_003319.4) | Missense Mutation (SNP) | VAF 32/253 reads (13%) | PolyPhen benign (0.039); catalogued as rs769936820, COSV100592112; called by muse, mutect2, varscan2
- TYR | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV54482318; called by muse, mutect2, varscan2
- ZFHX4 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99265978; called by muse, mutect2, varscan2
- ZFHX4 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265984; called by muse, mutect2, varscan2
- ZFHX4 | c.5176C>A p.P1726T | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.998); catalogued as rs371535436; called by muse, mutect2, varscan2
- ZFP91 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV60160382; called by muse, mutect2
- ZNF358 | c.1514A>T p.D505V | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs1039423100; called by muse, mutect2, varscan2
- ZNF608 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1438678321; called by muse, mutect2
- ZNF676 | c.1310C>T p.S437F (on ENST00000650058; = p.S405F on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as COSV101236347, COSV68094010; called by muse, mutect2
- ABCD1 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ABRA | c.35del p.P12Qfs*113 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel
- ACAD9 | c.1809G>T p.Q603H | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2
- ACAD9 | c.1838G>C p.C613S | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.495); called by muse, mutect2
- ACE | c.2420A>T p.E807V | Missense Mutation (SNP) | VAF 83/550 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ACER3 | c.92T>G p.I31S | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ACSM1 | c.1198-2_1205del p.X400_splice | Splice Site (DEL) | VAF 28/232 reads (12%) | called by mutect2, pindel
- ACTN4 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ADCY3 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG4 | c.7234A>G p.T2412A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD26 | c.2350T>A p.W784R | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ANKRD26 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ANKRD26 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AOC1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- AP1B1 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOBEC3B | c.600del p.F200Lfs*31 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.4041G>T p.R1347S (on ENST00000310343 / NM_001378025.1; = p.R998S on NM_014715.4) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ARHGEF19 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- ARMC6 | c.279G>T p.Q93H (on ENST00000392336; = p.Q68H on NM_033415.4) | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2
- ARMC9 | c.57A>T p.L19F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by mutect2, varscan2
- ASPA | c.636A>T p.G212= | Splice Region (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- ASRGL1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/98 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- AXL | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- BABAM1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- BCO2 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.248); called by muse, mutect2
- BIRC7 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CADM1 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 44/418 reads (11%) | called by muse, mutect2, varscan2
- CADPS2 | c.1915T>A p.C639S | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CATSPER1 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CCBE1 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CD207 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, mutect2
- CD8A | c.706T>C p.*236Qext*37 | Nonstop Mutation (SNP) | VAF 73/577 reads (13%) | called by muse, mutect2, varscan2
- CHMP7 | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2
- CLCA1 | c.1391A>T p.Q464L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); called by muse, mutect2
- CLHC1 | c.201C>A p.Y67* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2
- CNTLN | c.855_881del p.F285_K294delinsL | In Frame Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- COL11A1 | c.1945-1G>T p.X649_splice | Splice Site (SNP) | VAF 38/365 reads (10%) | called by muse, mutect2, varscan2
- COL3A1 | c.168C>G p.D56E | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- COMP | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 77/666 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- COPA | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- COPB2 | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- CROCC | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 32/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSF2RB | c.2566C>G p.Q856E | Missense Mutation (SNP) | VAF 88/590 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CSMD3 | c.7727C>A p.P2576H (on ENST00000297405 / NM_001363185.1; = p.P2472H on NM_052900.3) | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CSMD3 | c.5895T>A p.C1965* (on ENST00000297405 / NM_001363185.1; = p.C1861* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- CSPG5 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAGLA | c.2452G>T p.G818C | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); called by muse, mutect2
- DGKQ | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DHX35 | c.1615G>T p.A539S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.248); called by muse, mutect2
- DIO2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.055); called by muse, mutect2
- DISP2 | c.3886G>T p.D1296Y | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DNAH10 | c.2382T>G p.H794Q (on ENST00000409039; = p.H733Q on NM_207437.3) | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EN1 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2
- ENTR1 | c.371A>T p.K124I (on ENST00000357365 / NM_001039707.2; = p.K101I on NM_006643.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- EPPK1 | c.5376G>T p.Q1792H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ERVV-2 | c.1459T>A p.S487T | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- FAP | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- FARP1 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 40/285 reads (14%) | called by muse, mutect2, varscan2
- FAT4 | c.7849G>T p.D2617Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- FCRL5 | c.193del p.E65Kfs*3 | Frame Shift Del (DEL) | VAF 35/264 reads (13%) | called by mutect2, pindel, varscan2
- FGB | c.424T>G p.S142A | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- FLNB | c.7613G>T p.S2538I | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- FMNL3 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FN1 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FOXE1 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.12005G>T p.W4002L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- GALNT8 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GALNTL5 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 49/432 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF3 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GDPD5 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GOLGA6L2 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLPH3 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRAMD1C | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- GREB1 | c.3567C>G p.I1189M | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.568); called by muse, mutect2
- GRIN2B | c.421T>G p.S141A | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- H3C1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HDLBP | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 29/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HEPACAM | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.412); called by muse, mutect2
- HHLA1 | c.1017T>A p.S339R | Missense Mutation (SNP) | VAF 53/471 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPSE2 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2
- HS3ST3A1 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HSPB6 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ICE1 | c.5350A>T p.K1784* | Nonsense Mutation (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- IFNA8 | c.38T>A p.V13E | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IFT122 | c.2594A>G p.Y865C (on ENST00000348417 / NM_052989.3; = p.Y806C on NM_018262.4) | Missense Mutation (SNP) | VAF 50/484 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- IGHV1-46 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 43/604 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- IGLV3-21 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IL21R | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ITGA8 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KBTBD11 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KCNA7 | c.1068G>C p.M356I | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- KCNH5 | c.1681_1682del p.A561Lfs*40 | Frame Shift Del (DEL) | VAF 53/415 reads (13%) | called by pindel, varscan2
- KCP | c.3949G>T p.G1317W (on ENST00000620378; = p.G1441W on NM_001366122.1) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KDM5C | c.2906C>G p.A969G | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- KIRREL3 | c.2190C>G p.S730R | Missense Mutation (SNP) | VAF 38/701 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2
- KLHDC8A | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL6 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- KMT2B | c.3131G>T p.G1044V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- LAMA1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMP5 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LEPR | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRGUK | c.2305G>T p.G769* | Nonsense Mutation (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- MAGEB6B | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAGEC1 | c.3250G>T p.V1084L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MAGEE1 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2
- MAP10 | c.2173T>C p.F725L | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2
- MAP11 | c.228_239del p.T77_A80del | In Frame Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- METTL4 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- MGAM | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- MMP9 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 147/718 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MORC1 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- MSTN | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC17 | c.11679C>A p.S3893R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MYH13 | c.5168A>C p.Q1723P | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MYH4 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO1E | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- MYO7A | c.3414G>C p.Q1138H | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDN | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLGN4X | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NPC1L1 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NPC1L1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NRG3 | c.246C>A p.S82R | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NRROS | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- NRROS | c.1993G>T p.V665L | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OPN4 | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 40/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- OR10X1 | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.259); called by muse, mutect2
- OR11H1 | c.705C>A p.S235R | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- OR1K1 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR8D1 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OTOGL | c.4393C>A p.L1465I (on ENST00000547103; = p.L1456I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- P2RX3 | c.1191C>A p.H397Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PADI2 | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PAPLN | c.931G>T p.G311C (on ENST00000554301; = p.G284C on NM_173462.4) | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCSK9 | c.1500G>C p.M500I | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGLYRP2 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.269); called by muse, mutect2
- PI4KA | c.3815A>T p.K1272M | Missense Mutation (SNP) | VAF 49/389 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PIK3R4 | c.3368G>A p.G1123D | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIP4K2A | c.144+1G>T p.X48_splice | Splice Site (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2, varscan2
- PIPOX | c.997C>G p.R333G | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PLCZ1 | c.774A>T p.E258D | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2
- PLEKHA5 | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PLXNA1 | c.1688G>T p.C563F | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PLXNA4 | c.1967G>T p.C656F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA8A | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by mutect2, varscan2
- POGLUT2 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2
- POLR2A | c.3775A>G p.I1259V | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- POTEC | c.1209A>T p.Q403H | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- POTEE | c.648C>A p.C216* | Nonsense Mutation (SNP) | VAF 11/195 reads (6%) | called by muse, varscan2
- PRB3 | c.674C>T p.P225L (on ENST00000381842; = p.P267L on NM_006249.5) | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRDM9 | c.75del p.D26Mfs*29 | Frame Shift Del (DEL) | VAF 27/260 reads (10%) | called by mutect2, pindel, varscan2
- PRPH | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- RAD54L | c.1734T>A p.C578* | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- RAI1 | c.5400C>A p.D1800E | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBL2 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM26 | c.2009A>C p.K670T (on ENST00000438737 / NM_001366735.2; = p.K672T on NM_001286631.1) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- RC3H1 | c.2286G>T p.M762I | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.095); called by muse, mutect2
- RGMA | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIMS1 | c.3362G>C p.R1121T | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2
- RNF150 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTN1 | c.44C>A p.A15D | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RXFP3 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 108/484 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.12659A>G p.E4220G | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2
- RYR3 | c.4471G>T p.D1491Y | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SCN3A | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SCUBE1 | c.1997G>T p.C666F | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SERINC2 | c.781-1G>A p.X261_splice (on ENST00000373709 / NM_178865.5; = p.X265_splice on NM_018565.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- SFMBT2 | c.2416-2A>C p.X806_splice | Splice Site (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- SH3GL3 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SH3YL1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.329); called by muse, mutect2
- SHANK2 | c.3217A>G p.T1073A | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2
- SIPA1L3 | c.2443A>G p.T815A | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.115); called by muse, mutect2
- SKOR2 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- SLC12A1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SLC1A2 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- SLC26A3 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC34A3 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 75/499 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC44A1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 107/547 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLX4 | c.4033C>A p.R1345S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORBS1 | c.2983G>C p.V995L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS1 | c.117del p.S40Rfs*34 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- SPAG7 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPATA31A7 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 32/692 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.041); called by muse, mutect2
- STIL | c.1268C>G p.S423* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- STRIP2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SYTL5 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- TIGD4 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TMC4 | c.745C>A p.R249S (on ENST00000617472 / NM_001145303.3; = p.R243S on NM_144686.4) | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.165); called by muse, mutect2
- TMEM219 | c.489G>T p.E163D | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMPRSS9 | c.2769C>G p.S923R (on ENST00000648592; = p.S889R on NM_182973.2) | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNFSF11 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 33/488 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2
- TNKS1BP1 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.273); called by muse, mutect2
- TOP2A | c.1500+1G>T p.X500_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- TPRA1 | c.323A>T p.N108I | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TRIO | c.7426A>T p.S2476C | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TRPA1 | c.368A>T p.N123I | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TTC28 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TTN | c.55153A>G p.K18385E (on ENST00000591111; = p.K10961E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | PolyPhen benign (0.011); called by muse, mutect2
- TVP23B | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UGT2B7 | c.706T>A p.Y236N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- UNC13A | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.927); called by muse, mutect2
- UNC45A | c.1055dup p.S353Lfs*28 | Frame Shift Ins (INS) | VAF 32/237 reads (14%) | called by mutect2, pindel, varscan2
- UPRT | c.500-1G>C p.X167_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- USH2A | c.13391G>A p.W4464* | Nonsense Mutation (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- USH2A | c.9511G>T p.V3171L | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- USP29 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- VAX2 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.374); called by muse, mutect2
- VWF | c.2963A>T p.Y988F | Missense Mutation (SNP) | VAF 54/431 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XIRP2 | c.4640C>A p.S1547Y (on ENST00000628543; = p.S1722Y on NM_152381.6) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XIRP2 | c.7775C>T p.A2592V (on ENST00000628543; = p.A2767V on NM_152381.6) | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2
- ZBTB45 | c.1447C>G p.P483A | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZBTB46 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZBTB46 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZDHHC8 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP91 | c.1513G>T p.G505* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- ZKSCAN2 | c.2230G>T p.G744W | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF493 | c.1364G>T p.S455I | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF516 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 59/716 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- ZNF532 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF665 | c.1044G>T p.Q348H (on ENST00000600412; = p.Q413H on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF732 | c.1673C>A p.P558H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2
- ZNF781 | c.977A>T p.H326L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF804B | c.2363G>T p.W788L | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.441); called by muse, mutect2
- ZNF804B | c.2364G>T p.W788C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNRF3 | c.665T>C p.F222S (on ENST00000544604 / NM_001206998.2; = p.F122S on NM_032173.3) | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCA13 | c.8502C>T p.N2834= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- ACAN | c.1956G>C p.T652= | Silent (SNP) | VAF 39/285 reads (14%) | called by muse, mutect2, varscan2
- AIPL1 | c.24C>T p.N8= | Silent (SNP) | VAF 93/477 reads (19%) | called by muse, mutect2, varscan2
- ALX1 | c.483C>G p.V161= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as COSV104414536; called by muse, mutect2, varscan2
- ANKK1 | c.1317G>T p.G439= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ARFGEF3 | c.2019C>T p.A673= | Silent (SNP) | VAF 34/262 reads (13%) | catalogued as rs1217485062; called by muse, mutect2, varscan2
- ARHGEF11 | c.2160G>T p.V720= | Silent (SNP) | VAF 45/269 reads (17%) | called by muse, mutect2, varscan2
- ARSG | c.717G>A p.R239= | Silent (SNP) | VAF 46/445 reads (10%) | catalogued as rs200147106; called by muse, mutect2
- ATP10A | c.3651C>A p.L1217= | Silent (SNP) | VAF 51/372 reads (14%) | called by muse, mutect2, varscan2
- BUB1 | c.3180A>G p.Q1060= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- CD4 | c.381C>A p.A127= | Silent (SNP) | VAF 42/400 reads (11%) | catalogued as COSV50594230; called by muse, mutect2, varscan2
- CD55 | c.30G>T p.A10= | Silent (SNP) | VAF 54/336 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.1977T>A p.I659= (on ENST00000297405 / NM_001363185.1; = p.I555= on NM_052900.3) | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- DAZL | c.612T>C p.V204= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- DCC | c.3798G>A p.P1266= | Silent (SNP) | VAF 48/340 reads (14%) | catalogued as rs762340413, COSV71436115, COSV71438408; called by muse, mutect2, varscan2
- DEFB118 | c.96G>T p.G32= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2
- DLG5 | c.3852G>T p.R1284= | Silent (SNP) | VAF 35/293 reads (12%) | called by muse, mutect2, varscan2
- DNMT3B | c.447G>T p.R149= | Silent (SNP) | VAF 92/544 reads (17%) | called by muse, mutect2, varscan2
- DNTT | c.342G>T p.G114= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- DPYSL5 | c.75G>A p.E25= | Silent (SNP) | VAF 40/460 reads (9%) | called by muse, mutect2
- EVI5 | c.1992A>G p.L664= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- FBXO3 | c.163A>C p.R55= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- GLP2R | c.588T>A p.A196= | Silent (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.447G>C p.G149= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- GPR25 | c.615G>C p.L205= | Silent (SNP) | VAF 48/396 reads (12%) | called by mutect2, varscan2
- HEATR5A | c.1026G>T p.P342= | Silent (SNP) | VAF 59/527 reads (11%) | catalogued as COSV66340072; called by muse, mutect2, varscan2
- HSF5 | c.1365A>G p.P455= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- IGHV7-81 | c.186A>G p.Q62= | Silent (SNP) | VAF 52/542 reads (10%) | called by muse, mutect2
- IGKV1D-42 | c.240C>A p.V80= | Silent (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- IPO4 | c.531C>T p.L177= | Silent (SNP) | VAF 32/367 reads (9%) | catalogued as rs76635618; called by muse, mutect2
- IRS2 | c.150G>T p.L50= | Silent (SNP) | VAF 20/196 reads (10%) | called by muse, varscan2
- ISLR2 | c.925C>T p.L309= | Silent (SNP) | VAF 54/420 reads (13%) | called by muse, mutect2, varscan2
- KLHDC10 | c.1245G>T p.A415= | Silent (SNP) | VAF 51/442 reads (12%) | catalogued as COSV59050036; called by muse, mutect2, varscan2
- KLHL14 | c.1530T>C p.I510= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- LMCD1 | c.543G>T p.L181= | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as COSV50087588; called by muse, mutect2, varscan2
- LRRC4 | c.276C>A p.A92= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99974877; called by muse, mutect2, varscan2
- MUC16 | c.30408C>G p.P10136= | Silent (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.21984C>G p.T7328= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- MYH7 | c.3393G>A p.K1131= | Silent (SNP) | VAF 40/694 reads (6%) | called by muse, mutect2
- MYLK | c.3531C>A p.G1177= | Silent (SNP) | VAF 24/513 reads (5%) | catalogued as COSV60616715; called by muse, mutect2
- NECAB1 | c.957T>C p.Y319= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- NLGN1 | c.765C>T p.I255= | Silent (SNP) | VAF 25/324 reads (8%) | called by muse, mutect2
- OR1D2 | c.498G>T p.V166= | Silent (SNP) | VAF 35/229 reads (15%) | called by muse, mutect2, varscan2
- OR2T34 | c.654C>A p.V218= | Silent (SNP) | VAF 60/437 reads (14%) | called by muse, mutect2, varscan2
- OR5B21 | c.408A>T p.A136= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- OR5B3 | c.561C>T p.C187= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs954660709; called by muse, mutect2
- OR5L1 | c.519G>T p.V173= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV61733974; called by muse, mutect2, varscan2
- OR6N2 | c.171A>T p.T57= | Silent (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- OR7C2 | c.762C>G p.G254= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV50180479; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1140A>G p.P380= (on ENST00000259318 / NM_001136562.3; = p.P611= on NM_007203.5) | Silent (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- PAPPA2 | c.87A>G p.T29= | Silent (SNP) | VAF 31/247 reads (13%) | catalogued as rs1210381671; called by muse, mutect2, varscan2
- PDCD11 | c.4929G>A p.E1643= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as COSV99588277; called by muse, mutect2
- PDE8A | c.264A>G p.K88= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- PENK | c.726C>A p.P242= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as COSV59240006; called by muse, mutect2, varscan2
- PEX1 | c.1323T>C p.I441= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- PKHD1 | c.4323T>C p.I1441= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- PRMT1 | c.702G>A p.E234= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV67159810; called by muse, mutect2, varscan2
- REC8 | c.367C>T p.L123= | Silent (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- REG3G | c.432C>A p.G144= | Silent (SNP) | VAF 10/161 reads (6%) | catalogued as COSV55451505; called by muse, mutect2
- RNF144A | c.774G>C p.G258= | Silent (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- RPIA | c.912C>T p.N304= | Silent (SNP) | VAF 29/304 reads (10%) | called by muse, mutect2
- RTP5 | c.1371G>A p.L457= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- SALL3 | c.2448C>A p.T816= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV101609917; called by muse, mutect2, varscan2
- SAMD9 | c.1404A>G p.V468= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as rs767256482, COSV66075611; called by muse, mutect2, varscan2
- SBSN | c.1305A>G p.K435= | Silent (SNP) | VAF 30/334 reads (9%) | catalogued as rs1490276214; called by muse, mutect2
- SIGLEC11 | c.1380G>T p.L460= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- SLC15A1 | c.819C>A p.L273= | Silent (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1200G>A p.T400= | Silent (SNP) | VAF 154/716 reads (22%) | catalogued as rs199564835, COSV54370092; called by muse, mutect2, varscan2
- SLC8A3 | c.2514G>T p.L838= (on ENST00000381269 / NM_183002.3; = p.L836= on NM_033262.4) | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- SLC9A4 | c.630C>A p.A210= | Silent (SNP) | VAF 28/359 reads (8%) | called by muse, mutect2
- SLIT2 | c.1185C>T p.L395= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- STAB2 | c.1977G>T p.P659= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as COSV66342498; called by muse, mutect2, varscan2
- TAS2R1 | c.534T>A p.S178= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- THBD | c.1653G>A p.E551= | Silent (SNP) | VAF 46/359 reads (13%) | catalogued as rs1308517114; called by muse, mutect2, varscan2
- THOC5 | c.1086G>T p.L362= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- TICAM1 | c.348G>T p.V116= | Silent (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- TMBIM4 | c.21G>A p.R7= | Silent (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2, varscan2
- TMEM108 | c.666C>A p.G222= | Silent (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- TMLHE | c.702C>T p.Y234= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57686208; called by muse, mutect2, varscan2
- TOGARAM2 | c.1149G>A p.E383= | Silent (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- TRPA1 | c.2190C>T p.L730= | Silent (SNP) | VAF 17/176 reads (10%) | catalogued as rs1239924176; called by muse, mutect2
- TRPA1 | c.366A>C p.A122= | Silent (SNP) | VAF 32/314 reads (10%) | called by mutect2, varscan2
- TTLL12 | c.1794G>A p.V598= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- TTN | c.93825G>A p.L31275= (on ENST00000591111; = p.L23851= on NM_003319.4) | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- USP24 | c.1413G>T p.S471= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- USP7 | c.1212A>G p.L404= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs988422870; called by muse, varscan2
- VIPR2 | c.573C>T p.H191= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- ZCCHC24 | c.165C>T p.F55= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs1484014133; called by muse, mutect2, varscan2
- ZNF266 | c.1317G>T p.L439= | Silent (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- ZNF639 | c.630G>A p.E210= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs1412158513, COSV100418437; called by muse, mutect2
- ZNF713 | c.45T>C p.S15= (on ENST00000633730 / NM_001366796.2; = p.S28= on NM_182633.3) | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs1458765986; called by muse, mutect2, varscan2
- AAK1 | c.2467+36G>C | Intron (SNP) | VAF 31/304 reads (10%) | called by muse, mutect2
- AC002511.3 | n.176C>A | RNA (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- AC012236.1 | n.454+56G>T | Intron (SNP) | VAF 51/423 reads (12%) | called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509063 C>T | 5'Flank (SNP) | VAF 11/79 reads (14%) | called by muse, varscan2
- AC107023.1 | n.26-6223G>T | Intron (SNP) | VAF 61/330 reads (18%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1039A>T | RNA (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- AOC4P | n.1380C>A | RNA (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- AP1B1 | c.2776-9C>T | Intron (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- AREG | c.311-34A>T | Intron (SNP) | VAF 29/205 reads (14%) | called by muse, varscan2
- ARHGEF4 | c.-283C>T | 5'UTR (SNP) | VAF 34/254 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.*1190dup | 3'UTR (INS) | VAF 10/110 reads (9%) | called by mutect2, pindel, varscan2
- ARPP19 | c.-36A>T | 5'UTR (SNP) | VAF 47/460 reads (10%) | called by muse, mutect2, varscan2
- C14orf39 | chr14:60433409 C>A | 3'Flank (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2
- CALCR | c.850+2057C>A | Intron (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- CCDC140 | n.624C>T | RNA (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- CDH15 | chr16:89168576 C>T | 5'Flank (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- CFAP46 | c.7584-130G>T | Intron (SNP) | VAF 96/389 reads (25%) | called by muse, mutect2, varscan2
- CHCHD4 | c.22+2680G>T | Intron (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- COLEC11 | chr2:3595028 G>C | 5'Flank (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- CXADRP2 | n.443G>T | RNA (SNP) | VAF 5/45 reads (11%) | called by mutect2, varscan2
- DLX1 | c.513+56G>T | Intron (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- DNAH8 | c.-41-4566G>A | Intron (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- DTNA | c.1094+1398G>T | Intron (SNP) | VAF 38/490 reads (8%) | called by muse, mutect2
- EEF1A1P22 | n.134G>T | RNA (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2
- FAM90A27P | n.1224C>T | RNA (SNP) | VAF 38/505 reads (8%) | called by muse, mutect2
- FLJ40288 | n.725C>A | RNA (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- GFM2 | c.*329G>T | 3'UTR (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4083+466G>T | Intron (SNP) | VAF 27/271 reads (10%) | called by muse, mutect2, varscan2
- IFNLR1 | c.510+26G>A | Intron (SNP) | VAF 24/165 reads (15%) | called by muse, mutect2, varscan2
- JMJD1C | c.-152G>T | 5'UTR (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- KRT6A | c.*9T>C | 3'UTR (SNP) | VAF 46/221 reads (21%) | catalogued as rs3204925; called by muse, mutect2, varscan2
- LILRB1 | c.-293G>A | 5'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- LINC00868 | n.830C>G | RNA (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- LIPH | c.*44C>A | 3'UTR (SNP) | VAF 19/149 reads (13%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85726A>G | Intron (SNP) | VAF 51/387 reads (13%) | called by muse, mutect2, varscan2
- MEX3B | c.256+188C>A | Intron (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- MS4A4A | c.42-2116A>T | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- MXI1 | c.-22C>T | 5'UTR (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- NCF1C | n.585C>A | RNA (SNP) | VAF 91/781 reads (12%) | called by muse, mutect2, varscan2
- NDUFS7 | chr19:1383859 G>T | 5'Flank (SNP) | VAF 100/510 reads (20%) | called by muse, mutect2, varscan2
- POLQ | chr3:121546472 G>T | 5'Flank (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- PPP5D1 | n.425A>G | RNA (SNP) | VAF 24/208 reads (12%) | catalogued as COSV70071434; called by muse, mutect2, varscan2
- PREX2 | c.2716-2901A>T | Intron (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- PTPRT | c.2176+12092G>A | Intron (SNP) | VAF 20/414 reads (5%) | catalogued as rs1162796558; called by muse, mutect2
- PVALEF | c.-473A>G | 5'UTR (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- PYGB | c.2178-38G>A | Intron (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- RAB18 | c.68+246G>T | Intron (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- RAD54L | c.1487-43T>C | Intron (SNP) | VAF 24/384 reads (6%) | catalogued as rs190162768; called by muse, mutect2
- RARA | c.*107G>T | 3'UTR (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- RARA | c.*108G>T | 3'UTR (SNP) | VAF 16/154 reads (10%) | catalogued as rs1389390755; called by muse, mutect2
- RBM10 | c.-158_-150del | 5'UTR (DEL) | VAF 26/171 reads (15%) | called by mutect2, pindel, varscan2
- RFLNA | c.208-17C>A | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- RNF212 | c.363-15T>C | Intron (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- RNMT | c.*2077A>G | 3'UTR (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- SAMD3 | c.-21-561G>A | Intron (SNP) | VAF 12/90 reads (13%) | catalogued as rs1353636471; called by muse, mutect2, varscan2
- SEZ6 | c.*200C>T | 3'UTR (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- SHISA9 | c.-18C>A | 5'UTR (SNP) | VAF 22/360 reads (6%) | called by muse, mutect2
- SPATA31C2 | n.2895G>C | RNA (SNP) | VAF 48/473 reads (10%) | called by muse, mutect2, varscan2
- SSPOP | n.2656C>T | RNA (SNP) | VAF 41/310 reads (13%) | called by muse, mutect2, varscan2
- TBX2 | c.1052-154G>C | Intron (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- TBXAS1 | c.539+24A>G | Intron (SNP) | VAF 39/404 reads (10%) | called by muse, mutect2
- TEDC1 | chr14:105491038 C>G | 5'Flank (SNP) | VAF 63/700 reads (9%) | called by muse, mutect2
- TMEM135 | c.-46G>T | 5'UTR (SNP) | VAF 44/406 reads (11%) | called by muse, mutect2
- TREX2 | c.-13G>A | 5'UTR (SNP) | VAF 20/232 reads (9%) | catalogued as rs1266970459; called by muse, mutect2
- TRIB2 | c.563+1186A>G | Intron (SNP) | VAF 45/286 reads (16%) | called by muse, mutect2, varscan2
- TVP23C | c.12+24G>T | Intron (SNP) | VAF 66/308 reads (21%) | catalogued as rs761627340; called by muse, varscan2
- ZNF99 | c.*3119G>T | 3'UTR (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
